FM case AD12026 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Other and unspecified urinary organs.
https://portal.gdc.cancer.gov/cases/4d86c4eb-3d7b-4455-a5da-52983c639a53

Male, 71.8 years: Urothelial carcinoma, NOS (ICD-O-3 8120/3) of the urethra; metastasis biopsied or resected from the liver. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Metastatic.
